TARGET case TARGET-30-PARNCW — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/155505ca-95bc-5815-91ed-cc794d6d89b7

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Age at index: 4 years; Vital status: Dead; Days to death: 972 days (2.7 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C49.0; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Classification of tumor: primary; Age at diagnosis: 4.5 years (1,639 days); Year of diagnosis: 2007; Days to last follow up: 972 days (2.7 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Necrosis percent: 5; Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 606 days (1.7 years); Days to first event: 606 days (1.7 years); First event: Progression.
- Days to follow up: 972 days (2.7 years); Year of follow up: 2010.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PARNCW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PARNCW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 972
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- MKI: Low
- ICDO Description: Connective, Subcutaneous and other Soft tissues of head, face, and neck (excludes Connective tissue of orbit C69.6 and Nasal cartilage C30.0) Connective, Subcutaneous and other Soft tissues of (see list under C49): . Cheek . Chin . Face . Forehead .
- Percent Necrosis: 5
- Percent Tumor v/s Stroma: 90/10
- Site of Relapse: Primary site
